Gene-level copy-number profile of tumor specimen TCGA-L3-A524-01A from TCGA case TCGA-L3-A524, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 45.9 years (16,765 days).
Specimen TCGA-L3-A524-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b7379f91-2af1-45a1-a8b6-d34711ae9d00.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L3-A524-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 828 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c86e9ecc-9540-4764-8552-5edff9f63185

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,223; copy number 2: 11,896; copy number 3: 18,306; copy number 4: 14,366; copy number 5: 4,493; copy number 6: 4,618; copy number 7: 1,066; copy number 8: 1,522; copy number 9: 1,053; copy number 10: 571; copy number 11: 64; copy number 12: 8; copy number 13: 93; copy number 14: 21; copy number 15: 58; copy number 16: 3; copy number 19: 152; copy number 21: 37; copy number 23: 105; copy number 27: 116; copy number 34: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L3-A524-01A-11D-A25M-01): tumor purity 0.59, ploidy 3.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,892 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,418,210–170,739,421, 355 genes, copy number 7–8 (broad region; genes not listed).
- chr2:76,185,020–76,399,490, 1 gene, copy number 7 (within-gene range 6–7): AC073091.1.
- chr2:76,260,755–84,040,720, 65 genes, copy number 7 (broad region; genes not listed).
- chr3:96,566,357–96,777,683, 6 genes, copy number 13: AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1.
- chr3:107,104,911–109,977,767, 47 genes, copy number 13: AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1.
- chr3:119,703,076–119,807,570, 1 gene, copy number 11 (within-gene range 5–11): AC069444.2.
- chr3:119,780,484–120,682,269, 24 genes, copy number 11–21: NR1I2, PHBP8, GSK3B, AC092910.4, AC078856.1, AC092910.1, AC092910.2, AC092910.3, RN7SL762P, RN7SL397P, GPR156, Y_RNA, AC063952.2, LRRC58, AC063952.1, AC063952.4, AC063952.3, FSTL1, MIR198, AC126182.3, AC126182.1, AC126182.2, NDUFB4, HGD.
- chr3:165,206,929–189,897,276, 420 genes, copy number 13–27 (within-gene range 4–27) (broad region; genes not listed).
- chr3:189,969,030–189,969,861, 1 gene, copy number 21: MTAPP2.
- chr5:23,013,048–45,895,970, 335 genes, copy number 8–10 (broad region; genes not listed).
- chr6:52,497,408–52,703,825, 7 genes, copy number 7: TRAM2, TRAM2-AS1, AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2.
- chr8:78,268,637–145,066,685, 1,061 genes, copy number 7–16 (within-gene range 5–16) (broad region; genes not listed).
- chr10:5,346,651–5,404,828, 3 genes, copy number 7: AL683826.1, UCN3, TUBAL3.
- chr11:95,482,406–95,748,715, 3 genes, copy number 7 (within-gene range 3–7): AP001790.1, AP000820.2, AP000820.1.
- chr12:14,942,031–16,037,381, 16 genes, copy number 7 (within-gene range 5–7): ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1, PTPRO, AC092183.1, EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP, DERA, EGLN3P1.
- chr12:52,948,871–97,761,859, 913 genes, copy number 7–12 (broad region; genes not listed).
- chr12:101,393,116–107,912,620, 133 genes, copy number 8 (broad region; genes not listed).
- chr14:18,333,726–26,208,424, 484 genes, copy number 7–9 (broad region; genes not listed).
- chr14:59,595,976–59,870,776, 1 gene, copy number 7 (within-gene range 4–7): RTN1.
- chr14:59,919,423–60,091,783, 3 genes, copy number 7 (within-gene range 4–7): AL133299.1, LRRC9, AL157911.1.
- chr14:71,932,429–75,955,079, 123 genes, copy number 7–9 (within-gene range 5–9) (broad region; genes not listed).
- chr14:77,024,543–77,259,495, 13 genes, copy number 7 (within-gene range 5–7): IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1.
- chr15:47,774,219–48,645,721, 16 genes, copy number 7 (within-gene range 4–7): LINC01491, AC092078.2, AC092078.1, AC092078.3, SLC24A5, MYEF2, CTXN2, SLC12A1, AC066612.1, AC066612.2, AC023355.1, Y_RNA, DUT, FBN1, AC022467.2, AC022467.1.
- chr15:70,321,576–71,063,989, 19 genes, copy number 8: AC048383.1, LINC02205, AC009434.1, LINC02204, AC087699.1, SALRNA3, SALRNA2, UACA, AC009269.2, AC009269.5, AC009269.3, AC009269.1, RPL29P30, LARP6, AC009269.4, LRRC49, KRT8P9, THAP10, RPL5P3.
- chr15:71,110,244–71,115,494, 1 gene, copy number 8: CT62.
- chr15:72,376,113–72,900,260, 23 genes, copy number 34: HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, AC103874.1, NPM1P42.
- chr20:2,380,901–4,685,148, 73 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr20:22,960,534–26,251,546, 105 genes, copy number 7–14 (broad region; genes not listed).
- chr20:49,721,949–53,875,557, 84 genes, copy number 8–13 (broad region; genes not listed).
- chr20:57,266,797–57,409,333, 10 genes, copy number 14 (within-gene range 2–14): AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38.
- chr22:19,941,371–26,169,341, 395 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr22:27,102,766–31,388,837, 151 genes, copy number 8–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,223. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
